Somatic mutation profile of tumor specimen C3N-01843-01 (aliquot CPT0098270009) from CPTAC case C3N-01843, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.8 years (25,136 days).
Specimen C3N-01843-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5e2e029-780c-493f-afa5-b5ef40cebf53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01843-31 (Blood Derived Normal), aliquot CPT0098310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c5f2f4e-d25e-491c-8805-c902d526673e

The open-access MAF lists 917 somatic variants for this specimen: 629 protein-altering or splice-affecting, 181 silent, 107 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 424, Silent 181, Frame Shift Del 117, Intron 59, Frame Shift Ins 39, Nonsense Mutation 18, 3'UTR 18, RNA 16, Splice Region 13, Splice Site 12, 5'UTR 7, 5'Flank 6.

Variants (750 of 917; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 74/263 reads (28%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATPAF2 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 122/373 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs746446116; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COX14 | c.81dup p.Y28Vfs*39 | Frame Shift Ins (INS) | VAF 105/336 reads (31%) | catalogued as rs34028295; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 50/221 reads (23%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064796923, COSV58294922; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 23/163 reads (14%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 89/251 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 74/257 reads (29%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 112/350 reads (32%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NKX3-2 | c.337del p.A113Pfs*11 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | catalogued as rs606231352, CX099329; ClinVar: pathogenic; called by mutect2, pindel
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 74/184 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 68/242 reads (28%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3608G>A p.R1203H | Missense Mutation (SNP) | VAF 188/571 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs770680174, CM1310765, COSV60803832; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 236/642 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ACACA | c.4957A>G p.M1653V | Missense Mutation (SNP) | VAF 127/405 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as rs779027254; called by muse, mutect2, varscan2
- ADAMTS16 | c.2656G>A p.G886R | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs762566566, COSV99943595; called by muse, mutect2
- ADGRD2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV58340848; called by muse, mutect2
- ADGRD2 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58342202; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADPRS | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as rs1272158177; called by muse, mutect2, varscan2
- ALAS1 | c.199+3_199+6del p.X67_splice | Splice Site (DEL) | VAF 58/179 reads (32%) | catalogued as rs768669096; called by mutect2, pindel
- ALK | c.4517C>T p.T1506M | Missense Mutation (SNP) | VAF 153/468 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765034301, COSV66557650; called by muse, mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 99/297 reads (33%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- AMIGO1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.349); catalogued as rs1200989755, COSV63990410; called by muse, mutect2, varscan2
- AMIGO3 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57540470; called by muse, mutect2, varscan2
- ANK2 | c.11801A>G p.D3934G | Missense Mutation (SNP) | VAF 137/556 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1408198357; called by muse, mutect2, varscan2
- ANKRD18A | c.1135dup p.M379Nfs*14 | Frame Shift Ins (INS) | VAF 33/101 reads (33%) | catalogued as rs1338085438; called by mutect2, pindel, varscan2
- ARC | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.432); catalogued as rs762668132, COSV63078481; called by muse, mutect2, varscan2
- ARHGAP11A | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100853240; called by muse, mutect2, varscan2
- ARL14EP | c.554G>T p.R185I | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV56342689; called by muse, mutect2, varscan2
- ASB18 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as rs768212844; called by muse, mutect2
- ATG2B | c.4919G>A p.R1640Q | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs759729158; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 51/180 reads (28%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATXN7 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs763204193; called by muse, mutect2, varscan2
- B3GNT7 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55006242; called by muse, mutect2, varscan2
- BRD2 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 152/441 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66373510; called by muse, mutect2, varscan2
- BRINP2 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.127); catalogued as COSV64177728; called by muse, mutect2, varscan2
- C17orf50 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as rs782385657; called by muse, mutect2, varscan2
- C3orf20 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs374324620; called by muse, mutect2, varscan2
- C5orf22 | c.772dup p.S258Ffs*25 | Frame Shift Ins (INS) | VAF 21/113 reads (19%) | catalogued as rs751259551; called by mutect2, varscan2
- C9orf131 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 37/324 reads (11%) | catalogued as rs144687989, COSV56610059; called by muse, varscan2
- CADM3 | c.1154G>A p.G385D (on ENST00000368125 / NM_001127173.3; = p.G419D on NM_021189.5) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63673587; called by muse, mutect2
- CALCOCO1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1030520322, COSV100017258; called by muse, mutect2, varscan2
- CAMK1G | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs1024283499; called by muse, mutect2, varscan2
- CAPN10 | c.1592dup p.S532Qfs*38 | Frame Shift Ins (INS) | VAF 48/195 reads (25%) | catalogued as rs779173614; called by pindel, varscan2
- CASP8 | c.626C>T p.S209L (on ENST00000432109 / NM_033355.3; = p.S226L on NM_001228.4) | Missense Mutation (SNP) | VAF 22/447 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1351320412, COSV51849767; called by muse, mutect2
- CBARP | c.1156G>A p.A386T (on ENST00000382477; = p.A366T on NM_152769.3) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1003819494; called by muse, mutect2, varscan2
- CBX2 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1285377681, COSV99490957; called by muse, mutect2, varscan2
- CCDC89 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV57034754; called by muse, mutect2
- CCNYL1 | c.199A>G p.S67G | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs1038254239; called by muse, mutect2, varscan2
- CCSAP | c.576del p.K192Nfs*58 | Frame Shift Del (DEL) | VAF 101/415 reads (24%) | catalogued as rs778010925; called by mutect2, pindel, varscan2
- CD247 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs750366836; called by muse, mutect2
- CD93 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs779569738, COSV55665675, COSV55667177, COSV99849651; called by muse, mutect2, varscan2
- CDC5L | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs778188821, COSV65176593; called by muse, mutect2, varscan2
- CER1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 117/318 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs576594082; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 36/130 reads (28%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP65 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs866148472; called by muse, mutect2, varscan2
- CILP2 | c.1801G>T p.G601W | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364884; called by muse, mutect2, varscan2
- CIZ1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs763060495; called by muse, mutect2, varscan2
- CMC4 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs782008762, COSV62898338; called by muse, varscan2
- CMTM8 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56780224; called by muse, mutect2, varscan2
- CNKSR2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs376909898, COSV54263568; called by muse, mutect2, varscan2
- CNKSR2 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs768216123, COSV54255395; called by muse, mutect2, varscan2
- CNPY4 | c.41del p.L14Wfs*11 | Frame Shift Del (DEL) | VAF 73/234 reads (31%) | catalogued as rs1347948509; called by mutect2, pindel, varscan2
- CNR1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs370487985; called by muse, mutect2, varscan2
- COL18A1 | c.3356G>C p.G1119A (on ENST00000359759 / NM_130444.3; = p.G884A on NM_030582.4) | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100645413; called by mutect2, varscan2
- COL18A1 | c.3911G>C p.G1304A (on ENST00000359759 / NM_130444.3; = p.G1069A on NM_030582.4) | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV60594293; called by mutect2, varscan2
- COL22A1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277322; called by muse, mutect2
- COL27A1 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs143993841; called by muse, mutect2, varscan2
- COL2A1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 141/431 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs371440147; called by muse, mutect2, varscan2
- COL5A1 | c.4508G>A p.R1503H | Missense Mutation (SNP) | VAF 193/439 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373653069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.6069G>T p.M2023I (on ENST00000312481; = p.M2019I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/373 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55211720; called by muse, mutect2, varscan2
- CPNE4 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV70194372; called by muse, mutect2, varscan2
- CTBP2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs1163110103; called by muse, mutect2
- CYP3A7 | c.432+1G>A p.X144_splice | Splice Site (SNP) | VAF 112/414 reads (27%) | catalogued as COSV60481674; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCHS1 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773823269, COSV100202608; called by muse, mutect2
- DDI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV56375816; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 28/195 reads (14%) | catalogued as rs759023106; called by mutect2, varscan2
- DLEC1 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57294547; called by muse, mutect2, varscan2
- DNAAF2 | c.1986_1988del p.N662del | In Frame Del (DEL) | VAF 80/254 reads (31%) | catalogued as rs1263064209; called by pindel, varscan2
- DNAH3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769073354, COSV54537817; called by muse, mutect2, varscan2
- DNAH9 | c.9890C>T p.T3297I | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs767305540, COSV52353119; called by muse, mutect2, varscan2
- DVL2 | c.1801del p.A601Qfs*80 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | catalogued as rs745455027; called by mutect2, pindel
- DYRK3 | c.1400del p.G467Vfs*21 | Frame Shift Del (DEL) | VAF 64/264 reads (24%) | catalogued as rs781995280, COSV100895769; called by mutect2, pindel, varscan2
- EIF3A | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV64961414; called by muse, varscan2
- ELAC2 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 34/555 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs773906264; called by muse, mutect2
- ELL2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs535173054, COSV52985678; called by muse, mutect2, varscan2
- ENKD1 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs752281547; called by muse, mutect2, varscan2
- EPHB3 | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266529706; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 20/122 reads (16%) | catalogued as rs756461692; called by mutect2, varscan2
- EPRS1 | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.148); catalogued as rs199712671, COSV100859506; called by mutect2, varscan2
- ERI3 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1295757105; called by muse, mutect2, varscan2
- ERICH6B | c.950del p.K317Rfs*18 | Frame Shift Del (DEL) | VAF 55/218 reads (25%) | catalogued as rs754232917, COSV100074795; called by mutect2, pindel, varscan2
- ESYT1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs773812390; called by muse, mutect2, varscan2
- FAM47B | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1449185540; called by muse, mutect2
- FANCD2 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 148/488 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249790407, COSV55034228; called by muse, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 124/416 reads (30%) | catalogued as rs747011618; called by mutect2, varscan2
- FBXO6 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779768582; called by muse, mutect2, varscan2
- FBXW10 | c.2852A>G p.N951S | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1344963921; called by mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 46/211 reads (22%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FHOD1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs774140986, COSV99264462; called by muse, mutect2, varscan2
- FKBP8 | c.1118G>A p.R373Q (on ENST00000222308 / NM_001308373.2; = p.R374Q on NM_012181.5) | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs762968551; called by muse, mutect2, varscan2
- FOXA3 | c.109del p.L37Sfs*5 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | catalogued as rs1405426085; called by mutect2, pindel, varscan2
- FOXA3 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 128/464 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1272245829; called by muse, mutect2
- FTCD | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs765154985; called by muse, mutect2, varscan2
- FUBP3 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1002967091, COSV60513795; called by muse, varscan2
- G6PC | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410392732, CM950490, CM990611, COSV53830915; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 66/254 reads (26%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GGCX | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV52089587; called by muse, mutect2, varscan2
- GIGYF2 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs532345734; called by muse, mutect2
- GLT6D1 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as rs778019494; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 68/215 reads (32%) | catalogued as rs768760517; called by mutect2, varscan2
- GPR155 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.71); catalogued as rs553833504, COSV55039957; called by muse, mutect2, varscan2
- GPR18 | c.587del p.F196Sfs*2 | Frame Shift Del (DEL) | VAF 77/270 reads (29%) | catalogued as rs748201402; called by mutect2, varscan2
- GPR26 | c.829dup p.V277Gfs*61 | Frame Shift Ins (INS) | VAF 137/352 reads (39%) | catalogued as rs1298420618; called by mutect2, pindel, varscan2
- GPT | c.819+6C>T | Splice Region (SNP) | VAF 206/497 reads (41%) | catalogued as rs746189243; called by muse, mutect2, varscan2
- GSTM4 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 32/630 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs375686135; called by muse, mutect2
- GYPA | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); catalogued as rs1292304365; called by muse, mutect2, varscan2
- H2AC1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.118); catalogued as rs775985152, COSV99219384; called by muse, mutect2, varscan2
- H3-4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 126/563 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs761689329, COSV64210682; called by muse, mutect2, varscan2
- H3C13 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 95/369 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.073); catalogued as rs1242181199; called by muse, mutect2, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | catalogued as rs747918697; called by mutect2, varscan2
- HOXD8 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs1422300404; called by muse, mutect2, varscan2
- HR | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV57193104; called by muse, mutect2, varscan2
- HYDIN | c.12297C>T p.G4099= | Splice Region (SNP) | VAF 26/90 reads (29%) | catalogued as rs765614220; called by muse, mutect2, varscan2
- IDH3G | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.106); catalogued as rs782814956; called by muse, mutect2, varscan2
- IFFO1 | c.1089dup p.R364Afs*19 (on ENST00000396840 / NM_001330324.2; = p.R367Afs*19 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 42/158 reads (27%) | catalogued as rs750779916; called by mutect2, varscan2
- IGSF9 | c.1028G>A p.R343H (on ENST00000368094 / NM_001135050.2; = p.R327H on NM_020789.4) | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as rs375390689, COSV63639427; called by muse, mutect2, varscan2
- IL12RB2 | c.1394del p.G465Vfs*7 | Frame Shift Del (DEL) | VAF 175/547 reads (32%) | catalogued as COSV52019818; called by mutect2, pindel, varscan2
- INPPL1 | c.2415G>A p.T805= | Splice Region (SNP) | VAF 42/142 reads (30%) | catalogued as COSV99996242; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | catalogued as rs760925109; called by mutect2, varscan2
- IRAG1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769411998, COSV70210597; called by muse, mutect2, varscan2
- ITGA4 | c.142del p.H48Tfs*21 | Frame Shift Del (DEL) | VAF 14/172 reads (8%) | catalogued as rs773618186; called by mutect2, pindel
- ITPKB | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 89/266 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1399583186, COSV55259532; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 25/96 reads (26%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 105/303 reads (35%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNK15 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 141/479 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs371342693; called by muse, mutect2, varscan2
- KCNV2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 204/545 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs766985581; called by muse, mutect2, varscan2
- KIF7 | c.1640dup p.R549Afs*40 | Frame Shift Ins (INS) | VAF 67/248 reads (27%) | catalogued as rs770571299; called by mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 99/183 reads (54%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KPRP | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs778878205; called by muse, mutect2, varscan2
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 96/162 reads (59%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- KRT9 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs762726903, COSV55853216; called by muse, mutect2, varscan2
- L1CAM | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 196/615 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as rs139197516, COSV100648976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.442del p.R148Gfs*24 | Frame Shift Del (DEL) | VAF 109/413 reads (26%) | catalogued as COSV70345971; called by mutect2, pindel, varscan2
- LAMB2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs772271317; called by muse, mutect2, varscan2
- LAMC3 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 184/620 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755886724; called by muse, mutect2, varscan2
- LGALS7B | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 176/1058 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs761105840; called by muse, mutect2, varscan2
- LHPP | c.362_363del p.V121Gfs*16 | Frame Shift Del (DEL) | VAF 108/389 reads (28%) | catalogued as rs759496330; called by pindel, varscan2
- LRRC7 | c.3545G>A p.G1182D (on ENST00000651989 / NM_001370785.2; = p.G1149D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.529); catalogued as COSV50416699; called by muse, mutect2, varscan2
- LRRN1 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1353585671; called by muse, mutect2, varscan2
- LZTS2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748691503; called by muse, mutect2, varscan2
- MADCAM1 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1421990438; called by muse, mutect2, varscan2
- MAGI1 | c.2900A>G p.Q967R (on ENST00000402939 / NM_001033057.2; = p.Q995R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs746069792; called by muse, mutect2
- MBNL2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 219/566 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100600522; called by muse, mutect2, varscan2
- MBOAT4 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1197969350; called by muse, mutect2, varscan2
- MESD | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 176/476 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1349975011, COSV55725254; called by muse, varscan2
- MGAT2 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 202/599 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1338743307; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 73/229 reads (32%) | catalogued as rs866533107; called by mutect2, pindel, varscan2
- MMP9 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as rs1179114145, COSV63433987; called by muse, mutect2, varscan2
- MN1 | c.246del p.L83Cfs*140 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | catalogued as COSV56557060; called by mutect2, pindel, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 56/218 reads (26%) | catalogued as rs753079987; called by mutect2, varscan2
- MRE11 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 109/337 reads (32%) | catalogued as rs587781384, CM1411643, COSV100119452; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- MRPL43 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs958238658; called by muse, mutect2
- MRTFB | c.2650dup p.R884Pfs*3 (on ENST00000571589 / NM_001365412.2; = p.R834Pfs*3 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 47/210 reads (22%) | catalogued as rs768684761; called by mutect2, varscan2
- MUC2 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs751342198; called by muse, mutect2, varscan2
- MYCN | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 48/399 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55257982, COSV99808532; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 164/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, varscan2
- MYO1G | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201539357, COSV51854126; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 67/181 reads (37%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- N4BP3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs769576239, COSV51065160; called by muse, mutect2, varscan2
- NCOR2 | c.6347T>C p.L2116P | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs764960724; called by muse, mutect2, varscan2
- NEO1 | c.2342A>G p.H781R | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1425426743; called by muse, mutect2, varscan2
- NEO1 | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs377510140; called by muse, mutect2, varscan2
- NKPD1 | c.2332del p.H778Tfs*98 | Frame Shift Del (DEL) | VAF 58/169 reads (34%) | catalogued as rs777176845; called by mutect2, pindel, varscan2
- NKTR | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs774412106, COSV99235413; called by muse, mutect2, varscan2
- NLRC5 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs200816547, COSV52657252; called by muse, mutect2
- NMUR2 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54916936; called by muse, mutect2, varscan2
- NR1D2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56992808; called by muse, mutect2, varscan2
- NSD3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57622406; called by muse, mutect2, varscan2
- NT5C1B | c.1640G>A p.R547H (on ENST00000359846 / NM_001199086.2; = p.R487H on NM_033253.4) | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577374217; called by muse, mutect2, varscan2
- NTAN1 | c.890del p.N297Mfs*63 | Frame Shift Del (DEL) | VAF 34/232 reads (15%) | catalogued as rs753931847; called by mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 25/221 reads (11%) | catalogued as rs772197760; called by mutect2, pindel
- NUP88 | c.1796del p.K599Rfs*4 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | catalogued as rs1396162133; called by pindel, varscan2
- OLFM1 | c.763G>A p.A255T (on ENST00000371793 / NM_001282611.2; = p.A237T on NM_014279.5) | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.906); catalogued as COSV53281568; called by muse, mutect2, varscan2
- OR13C4 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs1354739226; called by muse, mutect2, varscan2
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | catalogued as rs749899868, COSV100237879; called by mutect2, pindel, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 66/192 reads (34%) | catalogued as rs747074822; called by mutect2, varscan2
- OR8K1 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1260710606; called by muse, mutect2
- OTOF | c.1469del p.P490Hfs*6 | Frame Shift Del (DEL) | VAF 68/178 reads (38%) | catalogued as rs779119416, CM024257; called by mutect2, varscan2
- PALB2 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 213/622 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs202194596, CM137608, COSV55166817; called by muse, mutect2, varscan2
- PCDHB14 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 165/483 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as rs782132041, COSV53391250; called by muse, mutect2, varscan2
- PCDHGA7 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs919957351, COSV53941030; called by muse, mutect2, varscan2
- PDE10A | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1327070657, COSV63105916; called by muse, mutect2, varscan2
- PDE6B | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 189/497 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs777799273; called by muse, mutect2, varscan2
- PDZD2 | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 120/359 reads (33%) | catalogued as COSV99225919; called by muse, mutect2, varscan2
- PHGR1 | c.109del p.H37Tfs*71 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | catalogued as rs1264440278; called by pindel, varscan2
- PHRF1 | c.4644del p.R1549Gfs*2 (on ENST00000264555 / NM_001286581.2; = p.R1548Gfs*2 on NM_020901.4) | Frame Shift Del (DEL) | VAF 56/218 reads (26%) | catalogued as rs1437690156; called by mutect2, pindel
- PIAS4 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs577156557; called by muse, mutect2, varscan2
- PIK3C2B | c.4756C>T p.R1586W | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1187199828; called by muse, mutect2, varscan2
- PLA2G4E | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs763944017, COSV68148709; called by muse, mutect2, varscan2
- PLD2 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs188978323; called by muse, mutect2, varscan2
- PLEC | c.5950C>T p.R1984W (on ENST00000322810 / NM_201380.4; = p.R1874W on NM_000445.5) | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1421391265, COSV59681069; called by muse, mutect2
- PLEKHG2 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as rs1007355498; called by muse, mutect2, varscan2
- PLEKHG2 | c.3964del p.Q1322Sfs*37 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs551236586; called by mutect2, varscan2
- PLIN4 | c.3538_3541del p.R1180* (on ENST00000301286; = p.R1195* on NM_001367868.2) | Frame Shift Del (DEL) | VAF 48/228 reads (21%) | catalogued as rs764244040; called by pindel, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 31/126 reads (25%) | catalogued as rs746342377; called by mutect2, varscan2
- PLXNA4 | c.4475G>A p.R1492H | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58103431; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); catalogued as rs780400425, COSV53454945; called by muse, mutect2, varscan2
- PPP2R2B | c.545A>G p.N182S (on ENST00000394409; = p.N248S on NM_181674.2) | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as rs774418279; called by muse, mutect2, varscan2
- PRICKLE3 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs782624063, COSV54295657; called by muse, mutect2, varscan2
- PRKCD | c.1300del p.D434Tfs*2 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | catalogued as rs1559629912, COSV57847601; called by mutect2, pindel, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs537061158; called by mutect2, varscan2
- PSMB4 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 59/322 reads (18%) | catalogued as rs1445295187; called by muse, mutect2, varscan2
- PTCH2 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1191742422; called by muse, mutect2, varscan2
- PTEN | c.962C>G p.T321R | Missense Mutation (SNP) | VAF 134/212 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV64294964; called by muse, varscan2
- PTPN6 | c.1756_1758del p.E586del | In Frame Del (DEL) | VAF 112/333 reads (34%) | catalogued as rs782028208; called by mutect2, pindel, varscan2
- RAB11FIP5 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 135/477 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs775520238, COSV50253717; called by muse, mutect2, varscan2
- RAB1B | c.241del p.A81Lfs*19 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV57581555; called by pindel, varscan2
- RAD54B | c.304+2T>C p.X102_splice | Splice Site (SNP) | VAF 34/214 reads (16%) | catalogued as COSV99890313; called by muse, mutect2, varscan2
- RAI1 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 198/594 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767147391; called by muse, mutect2, varscan2
- RASA2 | c.1904G>A p.S635N | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs779954976; called by muse, mutect2, varscan2
- RBM20 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 71/246 reads (29%) | catalogued as rs794729150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM6 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs768599973; called by muse, mutect2, varscan2
- RBP3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs782172169; called by muse, mutect2
- RFX5 | c.116+1G>A p.X39_splice | Splice Site (SNP) | VAF 92/484 reads (19%) | catalogued as rs972632936, COSV51838069; called by muse, mutect2, varscan2
- RGS12 | c.2632C>T p.R878* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as rs558310970; called by muse, mutect2
- RPGRIP1 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs754461580, COSV52849598; called by muse, varscan2
- RPS6KA2 | c.1365A>C p.E455D | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1454861783; called by muse, mutect2, varscan2
- RTN4R | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 112/280 reads (40%) | catalogued as COSV50380621; called by muse, mutect2, varscan2
- SAFB2 | c.2471dup p.Y825Lfs*9 | Frame Shift Ins (INS) | VAF 40/128 reads (31%) | catalogued as rs759920279; called by mutect2, varscan2
- SBF1 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs374897003; called by muse, mutect2, varscan2
- SBK2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as rs1001265594, COSV100705258; called by muse, mutect2
- SCLY | c.140C>T p.T47M (on ENST00000651534; = p.T39M on NM_016510.7) | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111411095; called by muse, mutect2, varscan2
- SDHA | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs773634017; called by muse, mutect2, varscan2
- SDHA | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 169/460 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV53767447; called by muse, mutect2, varscan2
- SEMA3F | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs776838630; called by muse, mutect2, varscan2
- SEMA3F | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs761760550; called by muse, mutect2, varscan2
- SERPINB8 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54639476; called by muse, mutect2, varscan2
- SH2D3A | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 108/283 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs562996882; called by muse, mutect2, varscan2
- SH3RF2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 102/397 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs140312306; called by muse, mutect2, varscan2
- SHANK1 | c.5885C>T p.A1962V | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1375945105; called by muse, mutect2
- SIPA1L3 | c.3547C>T p.P1183S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767998099, COSV55922235; called by muse, varscan2
- SLAMF7 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as rs769137492; called by muse, mutect2
- SLC10A2 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV55357206; called by muse, mutect2, varscan2
- SLC12A7 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 126/336 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99369098; called by muse, mutect2, varscan2
- SLC24A2 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs139901121; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 76/252 reads (30%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC26A8 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs775225736, COSV62885640; called by muse, mutect2, varscan2
- SLC34A3 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs367896891; called by muse, mutect2, varscan2
- SLC35D2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV53563219; called by muse, mutect2, varscan2
- SLC38A7 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs775170555; called by muse, mutect2, varscan2
- SLC43A3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs749643960, COSV61450086; called by muse, mutect2
- SLC45A1 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs890920787; called by muse, mutect2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLFN13 | c.1877G>T p.R626I | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1277354779, COSV53194411, COSV99539699; called by muse, mutect2, varscan2
- SLITRK2 | c.799A>G p.S267G | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV59428766; called by muse, mutect2, varscan2
- SMTN | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200037739, COSV60778916; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 24/274 reads (9%) | catalogued as rs747405143; called by mutect2, pindel
- SNAPC4 | c.4094G>A p.R1365Q | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs757686250; called by muse, mutect2, varscan2
- SPPL2B | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs749678289, COSV101194583; called by muse, mutect2, varscan2
- SPRR2A | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.951); catalogued as COSV101198772; called by muse, mutect2, varscan2
- SPTBN1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs777810695, COSV61691150; called by muse, mutect2
- SQSTM1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1267306593, COSV62434318; called by muse, mutect2, varscan2
- SREBF2 | c.2738+7A>G | Splice Region (SNP) | VAF 131/485 reads (27%) | catalogued as rs768803637; called by muse, mutect2, varscan2
- STRA6 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100121371; called by muse, mutect2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 80/258 reads (31%) | catalogued as rs747316268, COSV52690552; called by mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.18817G>A p.E6273K (on ENST00000367255 / NM_182961.4; = p.E6202K on NM_033071.3) | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs201346604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYS1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs201471133, COSV54782446; called by muse, mutect2, varscan2
- SYTL4 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99343514; called by muse, mutect2, varscan2
- TACC2 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs142091094; called by muse, mutect2, varscan2
- TAF4 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as COSV53337149; called by muse, mutect2, varscan2
- TBC1D2 | c.1933C>T p.H645Y | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs201610345; called by muse, mutect2, varscan2
- TBC1D9B | c.1247G>A p.S416N | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1406037270; called by muse, mutect2
- TBX5 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1555226329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 48/161 reads (30%) | catalogued as rs758822980; called by mutect2, varscan2
- TCHH | c.4769G>A p.R1590H | Missense Mutation (SNP) | VAF 58/573 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as rs758316622; called by muse, mutect2, varscan2
- TDRD9 | c.1378+2T>C p.X460_splice | Splice Site (SNP) | VAF 38/116 reads (33%) | catalogued as COSV100175798; called by muse, mutect2, varscan2
- TEX38 | c.493del p.L165Cfs*2 | Frame Shift Del (DEL) | VAF 92/253 reads (36%) | catalogued as rs776783500; called by mutect2, pindel, varscan2
- TFE3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV59947750; called by muse, mutect2, varscan2
- THAP5 | c.297del p.K99Nfs*25 (on ENST00000415914 / NM_001130475.3; = p.K57Nfs*25 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs745348876; called by mutect2, varscan2
- THBS3 | c.914del p.P305Lfs*181 | Frame Shift Del (DEL) | VAF 38/193 reads (20%) | catalogued as rs757853564; called by mutect2, pindel, varscan2
- TINAG | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52510147; called by muse, mutect2, varscan2
- TMEM203 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV58808894; called by muse, mutect2, varscan2
- TMEM81 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as rs1233118112; called by muse, mutect2, varscan2
- TMF1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs762546989, COSV68374461; called by muse, mutect2, varscan2
- TNFRSF4 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs751046781; called by muse, mutect2, varscan2
- TNRC6C | c.3467A>G p.Q1156R | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56951397; called by muse, mutect2
- TOP1MT | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138642876; called by muse, mutect2, varscan2
- TRANK1 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs745527401, COSV57151749, COSV57155023; called by muse, mutect2, varscan2
- TRIM56 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs781559092, COSV60158108; called by muse, mutect2, varscan2
- TRIM67 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1203916931; called by muse, mutect2, varscan2
- TRIP12 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757346052, COSV52262477; called by muse, mutect2, varscan2
- TRIP4 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.086); catalogued as rs202164400, COSV56030712; called by muse, varscan2
- TRMT10B | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs540903572, COSV53052015; called by muse, mutect2, varscan2
- TTBK1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.885); catalogued as rs758989379, COSV52488215; called by muse, mutect2, varscan2
- TTC36 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs781853214; called by muse, mutect2, varscan2
- TYR | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs141930049; called by muse, mutect2, varscan2
- UBQLN4 | c.426del p.S144Lfs*28 | Frame Shift Del (DEL) | VAF 53/213 reads (25%) | catalogued as COSV64145892; called by mutect2, pindel, varscan2
- UNC5CL | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 149/406 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs920429480; called by muse, mutect2, varscan2
- URB2 | c.4276C>T p.R1426C | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs749714335; called by muse, mutect2, varscan2
- USP7 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61214963; called by muse, mutect2, varscan2
- VAT1 | c.752_754del p.K251del | In Frame Del (DEL) | VAF 12/96 reads (13%) | catalogued as rs769709729; called by pindel, varscan2
- VPS13B | c.5441C>T p.A1814V | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV62154685; called by muse, mutect2, varscan2
- VWA3A | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs758832147, COSV67011343; called by muse, mutect2, varscan2
- WDR87 | c.8159dup p.E2721Gfs*44 | Frame Shift Ins (INS) | VAF 58/249 reads (23%) | catalogued as rs1555756562; called by mutect2, varscan2
- WDR88 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745463721; called by muse, mutect2, varscan2
- WNT16 | c.500dup p.C168Lfs*4 (on ENST00000222462 / NM_057168.2; = p.C158Lfs*4 on NM_016087.2) | Frame Shift Ins (INS) | VAF 56/430 reads (13%) | catalogued as rs771899177; called by mutect2, varscan2
- XDH | c.1664dup p.A556Sfs*15 | Frame Shift Ins (INS) | VAF 130/399 reads (33%) | catalogued as rs777123723; called by mutect2, pindel, varscan2
- XPO6 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58973403; called by muse, mutect2, varscan2
- ZC3H12D | c.967del p.R323Gfs*175 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs1374931227; called by mutect2, pindel, varscan2
- ZFHX4 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573775710; called by muse, mutect2, varscan2
- ZMYND19 | c.236del p.G79Afs*14 | Frame Shift Del (DEL) | VAF 69/249 reads (28%) | catalogued as rs753541275; called by mutect2, pindel, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 120/344 reads (35%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF518A | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1489357478; called by muse, mutect2, varscan2
- ZNF554 | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV57885727; called by muse, mutect2, varscan2
- ZNF85 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV56021044; called by muse, mutect2, varscan2
- ZNF98 | c.305del p.N102Ifs*6 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs757764317, COSV63337477; called by mutect2, varscan2
- ZNRF1 | c.199del p.V67Cfs*96 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | catalogued as rs1555508498; called by mutect2, pindel, varscan2
- ABAT | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 205/579 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA2 | c.187del p.L63Wfs*19 (on ENST00000614293; = p.L33Wfs*19 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- ABR | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC006059.2 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACACA | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 156/428 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF1 | c.2323del p.Q775Sfs*144 | Frame Shift Del (DEL) | VAF 73/304 reads (24%) | called by mutect2, pindel, varscan2
- AGAP4 | c.1794G>T p.E598D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.174); called by mutect2, varscan2
- ALDH18A1 | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK3 | c.11759G>T p.R3920M | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ANKH | c.706_709del p.K236Cfs*2 | Frame Shift Del (DEL) | VAF 158/536 reads (29%) | called by pindel, varscan2
- ANKRD26 | c.872del p.N291Ifs*2 | Frame Shift Del (DEL) | VAF 68/484 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 149/433 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANTXRL | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- APBA1 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APP | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ARFGAP3 | c.866A>T p.D289V | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ARHGEF11 | c.2366A>G p.H789R | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF12 | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ARID1A | c.1376_1377del p.P459Qfs*163 | Frame Shift Del (DEL) | VAF 90/240 reads (38%) | called by mutect2, pindel
- ARIH1 | c.1003A>C p.N335H | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ARMCX5 | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ATP13A4 | c.2182G>T p.A728S | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- B4GALNT4 | c.295dup p.A99Gfs*29 | Frame Shift Ins (INS) | VAF 80/252 reads (32%) | called by mutect2, varscan2
- BAAT | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 113/317 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- BAX | c.278del p.F93Sfs*40 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- BCKDK | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCOR | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- BHLHE41 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMS1 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- C1orf56 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- C2CD4B | c.1072del p.L358Wfs*24 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel
- C6orf132 | c.3173del p.G1058Afs*5 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- CALML4 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- CASC3 | c.1378A>C p.S460R | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCDC168 | c.16711_16714del p.D5571Kfs*25 | Frame Shift Del (DEL) | VAF 69/255 reads (27%) | called by mutect2, pindel, varscan2
- CCDC34 | c.824dup p.F276Vfs*11 | Frame Shift Ins (INS) | VAF 82/240 reads (34%) | called by mutect2, varscan2
- CD177 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CDK14 | c.229C>T p.Q77* (on ENST00000380050 / NM_001287135.2; = p.Q59* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 134/430 reads (31%) | called by muse, mutect2, varscan2
- CDX4 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CENPC | c.2130A>G p.S710= | Splice Region (SNP) | VAF 78/240 reads (33%) | called by muse, mutect2, varscan2
- CEP192 | c.7196del p.N2399Tfs*12 | Frame Shift Del (DEL) | VAF 96/277 reads (35%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 94/354 reads (27%) | called by mutect2, varscan2
- CHML | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CHRNA5 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CIC | c.4555A>G p.M1519V | Missense Mutation (SNP) | VAF 30/413 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- CLIC2 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLK2 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 20/661 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- CLOCK | c.1349-2A>G p.X450_splice | Splice Site (SNP) | VAF 47/342 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.1767G>T p.E589D | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- COG2 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- COLCA2 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- COMMD6 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPA1 | c.328del p.R110Gfs*51 | Frame Shift Del (DEL) | VAF 41/363 reads (11%) | called by mutect2, pindel
- CPED1 | c.1526T>C p.F509S | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- CTDSPL | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- CTSC | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 176/501 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CYFIP2 | c.1024del p.Q342Sfs*31 | Frame Shift Del (DEL) | VAF 20/230 reads (9%) | called by mutect2, pindel
- CYP27C1 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- DAAM1 | c.2734T>C p.Y912H | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DACH2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DCAF1 | c.2809del p.Q937Rfs*4 | Frame Shift Del (DEL) | VAF 106/394 reads (27%) | called by mutect2, pindel, varscan2
- DCDC1 | c.1031G>T p.R344I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- DCHS1 | c.6985G>T p.G2329C | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX43 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- DEFB129 | c.129del p.E44Rfs*7 | Frame Shift Del (DEL) | VAF 11/135 reads (8%) | called by mutect2, pindel
- DIS3 | c.1333del p.S445Hfs*20 | Frame Shift Del (DEL) | VAF 76/235 reads (32%) | called by mutect2, pindel, varscan2
- DMGDH | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 102/333 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DMKN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DMRT3 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC7 | c.597T>C p.A199= | Splice Region (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- DTX1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- DUSP8 | c.821+1G>A p.X274_splice | Splice Site (SNP) | VAF 59/158 reads (37%) | called by muse, mutect2, varscan2
- DYRK4 | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- E2F8 | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EFCAB5 | c.2891C>T p.A964V | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EHHADH | c.1751A>C p.K584T | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- EIF4G2 | c.2556del p.F852Lfs*22 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- ENGASE | c.2096A>G p.D699G | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPB42 | c.655-7dup | Splice Region (INS) | VAF 37/83 reads (45%) | called by mutect2, pindel, varscan2
- ERCC6 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- FAM120B | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, varscan2
- FAM13B | c.1019A>G p.H340R | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2
- FAM234A | c.341del p.N114Tfs*97 | Frame Shift Del (DEL) | VAF 43/186 reads (23%) | called by mutect2, pindel, varscan2
- FAM71E2 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FBRSL1 | c.896del p.P299Rfs*115 | Frame Shift Del (DEL) | VAF 40/197 reads (20%) | called by mutect2, pindel, varscan2
- FBXL7 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 151/427 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FBXO47 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FERD3L | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FLT4 | c.2168-6C>A | Splice Region (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- FOXP1 | c.1653-2A>G p.X551_splice | Splice Site (SNP) | VAF 44/434 reads (10%) | called by muse, mutect2, varscan2
- FREM1 | c.4931del p.N1644Mfs*13 | Frame Shift Del (DEL) | VAF 90/283 reads (32%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.3654G>C p.M1218I | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- FSIP2 | c.19464T>G p.I6488M | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FUBP1 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 71/207 reads (34%) | called by muse, mutect2, varscan2
- FUT10 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 29/495 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GATA1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GCDH | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 71/568 reads (13%) | called by muse, mutect2, varscan2
- GDF10 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GIPC3 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.325); called by muse, mutect2
- GPAM | c.1802dup p.P602Sfs*3 | Frame Shift Ins (INS) | VAF 118/382 reads (31%) | called by mutect2, pindel, varscan2
- GPR153 | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- GPR39 | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GPS1 | c.152A>T p.Y51F | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GRM8 | c.1942T>C p.C648R | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1632T>A p.F544L | Missense Mutation (SNP) | VAF 18/531 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2
- GTF3A | c.954del p.K318Nfs*111 | Frame Shift Del (DEL) | VAF 54/159 reads (34%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.1184dup p.P396Tfs*27 | Frame Shift Ins (INS) | VAF 84/273 reads (31%) | called by mutect2, pindel, varscan2
- HACE1 | c.1489A>T p.I497F | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 48/175 reads (27%) | called by mutect2, varscan2
- HMCN1 | c.1000del p.T334Qfs*26 | Frame Shift Del (DEL) | VAF 114/492 reads (23%) | called by mutect2, varscan2
- HMGXB3 | c.1739C>A p.P580H (on ENST00000613459; = p.P334H on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMOX1 | c.747dup p.V250Rfs*147 | Frame Shift Ins (INS) | VAF 62/542 reads (11%) | called by mutect2, pindel
- HSPH1 | c.2250dup p.V751Sfs*6 | Frame Shift Ins (INS) | VAF 72/198 reads (36%) | called by mutect2, pindel, varscan2
- IFT140 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF9 | c.2531C>A p.P844H (on ENST00000368094 / NM_001135050.2; = p.P828H on NM_020789.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGSF9B | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IL17REL | c.837del p.S280Pfs*47 | Frame Shift Del (DEL) | VAF 139/468 reads (30%) | called by pindel, varscan2
- INSM2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ITPR2 | c.2260A>T p.T754S | Missense Mutation (SNP) | VAF 174/438 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 62/179 reads (35%) | called by mutect2, pindel, varscan2
- KAT8 | c.227T>G p.I76S | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KDM3A | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, varscan2
- KIAA1109 | c.6457G>T p.V2153L | Missense Mutation (SNP) | VAF 101/355 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KIAA1109 | c.8489A>G p.H2830R | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIAA1217 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- KIAA2012 | c.1726G>T p.G576W | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIRREL2 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- KLF8 | c.1055A>G p.H352R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRTAP4-4 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- LARP1B | c.1937del p.P646Lfs*2 | Frame Shift Del (DEL) | VAF 70/231 reads (30%) | called by mutect2, pindel, varscan2
- LILRA2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- LIPC | c.88+8C>T | Splice Region (SNP) | VAF 125/444 reads (28%) | called by muse, mutect2, varscan2
- LRRC41 | c.1752A>G p.I584M | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.221); called by muse, mutect2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 143/451 reads (32%) | called by mutect2, pindel, varscan2
- LYPD5 | c.357del p.N120Tfs*2 (on ENST00000377950 / NM_001031749.3; = p.N77Tfs*2 on NM_182573.2) | Frame Shift Del (DEL) | VAF 64/232 reads (28%) | called by mutect2, pindel, varscan2
- LYPD6B | c.508T>C p.Y170H (on ENST00000409029 / NM_001317004.1; = p.Y194H on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, varscan2
- MAGEB2 | c.249dup p.G84Rfs*8 | Frame Shift Ins (INS) | VAF 90/300 reads (30%) | called by mutect2, pindel, varscan2
- MAGEB3 | c.430del p.S144Afs*25 | Frame Shift Del (DEL) | VAF 34/222 reads (15%) | called by mutect2, pindel, varscan2
- MARCKSL1 | c.246del p.K83Rfs*18 | Frame Shift Del (DEL) | VAF 48/142 reads (34%) | called by mutect2, pindel, varscan2
- MBD1 | c.1626_1636delinsC p.D543Rfs*27 (on ENST00000269468 / NM_001323950.1; = p.D441Rfs*27 on NM_002384.2) | Frame Shift Del (DEL) | VAF 75/399 reads (19%) | called by pindel, varscan2*
- MCL1 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- MCM3AP | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MCOLN3 | c.1078del p.M360Wfs*8 | Frame Shift Del (DEL) | VAF 19/182 reads (10%) | called by mutect2, pindel, varscan2
- METRNL | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFSD12 | c.363del p.T122Rfs*15 | Frame Shift Del (DEL) | VAF 25/160 reads (16%) | called by mutect2, pindel, varscan2
- MGAT5B | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MINAR1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MTURN | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MYH14 | c.2084G>A p.C695Y | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2
- MYL2 | c.94-1G>T p.X32_splice | Splice Site (SNP) | VAF 151/440 reads (34%) | called by muse, mutect2, varscan2
- MYO15B | c.8180dup p.Q2728Afs*73 | Frame Shift Ins (INS) | VAF 72/263 reads (27%) | called by mutect2, pindel, varscan2
- MYO1B | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- MYO5A | c.3651dup p.L1218Tfs*4 | Frame Shift Ins (INS) | VAF 62/353 reads (18%) | called by mutect2, pindel, varscan2
- NBEA | c.3136dup p.S1046Kfs*9 | Frame Shift Ins (INS) | VAF 131/357 reads (37%) | called by mutect2, pindel, varscan2
- NCAPG2 | c.499T>G p.F167V | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NDUFA9 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NES | c.863T>G p.L288R | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NHS | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 137/410 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NKAPD1 | c.656T>C p.L219S (on ENST00000280352 / NM_001082970.2; = p.L220S on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRC4 | c.1943C>A p.A648D | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NLRP4 | c.142A>T p.K48* | Nonsense Mutation (SNP) | VAF 68/238 reads (29%) | called by muse, mutect2, varscan2
- NME1-NME2 | c.704A>G p.N235S (on ENST00000555572; = p.N210S on NM_001018136.3) | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- NMT2 | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOP9 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 118/385 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NPM3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- NR1H3 | c.582del p.R195Gfs*19 | Frame Shift Del (DEL) | VAF 77/195 reads (39%) | called by mutect2, pindel, varscan2
- NVL | c.762del p.L255* | Frame Shift Del (DEL) | VAF 74/338 reads (22%) | called by mutect2, pindel, varscan2
- OBSCN | c.14737dup p.D4913Gfs*53 | Frame Shift Ins (INS) | VAF 104/465 reads (22%) | called by mutect2, pindel, varscan2
- OR13A1 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- OSBP | c.1337T>A p.M446K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- P2RY4 | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPN1L | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PAK4 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PAX3 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 157/442 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PC | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 146/389 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCCA | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- PHF20 | c.2939del p.P980Lfs*18 | Frame Shift Del (DEL) | VAF 57/189 reads (30%) | called by mutect2, pindel, varscan2
- PHF3 | c.1735dup p.T579Nfs*20 | Frame Shift Ins (INS) | VAF 64/194 reads (33%) | called by mutect2, varscan2
- PHIP | c.2970dup p.Q991Tfs*5 | Frame Shift Ins (INS) | VAF 27/231 reads (12%) | called by mutect2, pindel, varscan2
- PIBF1 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PIGF | c.547-2A>G p.X183_splice | Splice Site (SNP) | VAF 68/250 reads (27%) | called by muse, mutect2, varscan2
- PIK3C2B | c.859del p.R287Afs*92 | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | called by mutect2, pindel, varscan2
- PKD2L2 | c.1793del p.L598Yfs*15 (on ENST00000508883 / NM_001300921.2; = p.L576Yfs*15 on NM_001258448.2) | Frame Shift Del (DEL) | VAF 66/233 reads (28%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 41/607 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLCB1 | c.1329dup p.Y444Ifs*18 | Frame Shift Ins (INS) | VAF 66/220 reads (30%) | called by mutect2, pindel, varscan2
- PLEC | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNPLA8 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR3A | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 60/565 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2
- POM121 | c.2094del p.A699Pfs*142 (on ENST00000434423; = p.A434Pfs*142 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 115/611 reads (19%) | called by mutect2, pindel, varscan2
- POTEI | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, varscan2
- POTEI | c.1555del p.R519Dfs*7 | Frame Shift Del (DEL) | VAF 29/236 reads (12%) | called by mutect2, pindel
- PPP1R10 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.967); called by muse, mutect2
- PPP1R3G | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PRICKLE4 | c.446G>A p.C149Y (on ENST00000359201; = p.C189Y on NM_013397.6) | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCB | c.744T>G p.D248E | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PRR12 | c.2036_2038del p.P679del (on ENST00000615927; = p.P1500del on NM_020719.3) | In Frame Del (DEL) | VAF 114/348 reads (33%) | called by pindel, varscan2
- PRR14L | c.4141G>T p.G1381W | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- PRRT4 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.02); called by muse, varscan2
- PRSS36 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 87/302 reads (29%) | called by muse, mutect2, varscan2
- PSMA5 | c.685T>G p.F229V | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSMB7 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMD12 | c.1048del p.R350Gfs*5 | Frame Shift Del (DEL) | VAF 43/126 reads (34%) | called by mutect2, pindel, varscan2
- PTEN | c.948_957del p.V317* | Frame Shift Del (DEL) | VAF 128/250 reads (51%) | called by pindel, varscan2
- PTPRN2 | c.2782A>C p.R928= | Splice Region (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2
- PTPRT | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 78/470 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- QDPR | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 148/471 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, varscan2
- R3HCC1L | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB6D | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RAI1 | c.2102del p.K701Rfs*118 | Frame Shift Del (DEL) | VAF 304/910 reads (33%) | called by mutect2, varscan2
- RALGPS1 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAP1A | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL1 | c.1984C>A p.Q662K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RBFOX2 | c.651A>C p.E217D (on ENST00000438146 / NM_001349995.2; = p.E147D on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- RBM10 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 238/642 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RBM14 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RBM46 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- RPRD2 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- RTTN | c.827del p.F276Sfs*69 | Frame Shift Del (DEL) | VAF 13/133 reads (10%) | called by mutect2, pindel
- RXFP2 | c.1855dup p.T619Nfs*29 | Frame Shift Ins (INS) | VAF 154/455 reads (34%) | called by mutect2, pindel, varscan2
- S1PR4 | c.220C>A p.H74N | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2
- SAMD12 | c.15T>C p.A5= | Splice Region (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- SAMD5 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD8 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SCAMP3 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- SCRIB | c.4669del p.Q1557Rfs*17 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- SETD3 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- SHPRH | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SIK3 | c.2377dup p.M794Hfs*32 (on ENST00000445177 / NM_001366686.2; = p.M752Hfs*32 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 76/230 reads (33%) | called by mutect2, pindel, varscan2
- SLC16A6 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.096); called by muse, mutect2
- SLC25A11 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A5 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLC25A5 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC26A9 | c.245dup p.S83Ifs*55 | Frame Shift Ins (INS) | VAF 48/227 reads (21%) | called by mutect2, pindel, varscan2
- SLC30A10 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SLC4A8 | c.397T>C p.W133R | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A2 | c.1345A>G p.K449E (on ENST00000494857 / NM_001370338.1; = p.K488E on NM_003046.6) | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SLC9A9 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 160/387 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SLC9B1 | c.307del p.Y103Ifs*17 | Frame Shift Del (DEL) | VAF 54/169 reads (32%) | called by mutect2, pindel, varscan2
- SMCR8 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SNTN | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2
- SOAT1 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOAT1 | c.1154del p.L385Cfs*66 | Frame Shift Del (DEL) | VAF 24/284 reads (8%) | called by mutect2, pindel
- SPATA31A3 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 102/545 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPATA31A6 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SPG11 | c.4340A>T p.Q1447L | Missense Mutation (SNP) | VAF 147/436 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPTBN5 | c.9863del p.G3288Afs*40 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.1784C>T p.A595V (on ENST00000621492; = p.A561V on NM_025248.3) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SRGAP2 | c.2320G>A p.G774R (on ENST00000624873 / NM_001170637.4; = p.G775R on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- STK11 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNGR3 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAB2 | c.1764+3_1764+8del p.X588_splice | Splice Site (DEL) | VAF 92/376 reads (24%) | called by mutect2, pindel, varscan2
- TAF3 | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2
- TAF4 | c.1485del p.T496Qfs*23 | Frame Shift Del (DEL) | VAF 42/151 reads (28%) | called by mutect2, pindel, varscan2
- TAPBP | c.1109del p.P370Qfs*33 | Frame Shift Del (DEL) | VAF 33/106 reads (31%) | called by mutect2, varscan2
- TBX2 | c.1378del p.L460Wfs*208 | Frame Shift Del (DEL) | VAF 67/204 reads (33%) | called by mutect2, pindel, varscan2
- TENM1 | c.3115C>A p.L1039M | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2
- THSD4 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- TIMP4 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- TMEM106A | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TMEM221 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TMEM63C | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- TOPAZ1 | c.4C>T p.R2* | Nonsense Mutation (SNP) | VAF 95/268 reads (35%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.1979G>A p.G660D | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- TRGV8 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TRMT2A | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TRPM4 | c.1467dup p.A490Sfs*13 | Frame Shift Ins (INS) | VAF 92/299 reads (31%) | called by mutect2, pindel, varscan2
- TRPV6 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- TRRAP | c.4310A>G p.Y1437C | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TTC28 | c.2983C>A p.L995M | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); called by muse, mutect2
- UBE2O | c.3208G>T p.G1070C | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR1 | c.2306T>C p.M769T | Missense Mutation (SNP) | VAF 156/381 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UCHL1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 161/472 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- UPRT | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP13 | c.1323_1325del p.S442del | In Frame Del (DEL) | VAF 52/190 reads (27%) | called by pindel, varscan2
- USP17L7 | c.113_114dup p.E39Lfs*33 | Frame Shift Ins (INS) | VAF 152/250 reads (61%) | called by mutect2, varscan2
- USP24 | c.5352G>T p.Q1784H | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP27X | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 83/187 reads (44%) | called by muse, mutect2, varscan2
- USP9X | c.6341del p.G2114Vfs*7 | Frame Shift Del (DEL) | VAF 177/527 reads (34%) | called by mutect2, pindel, varscan2
- USPL1 | c.2999A>G p.D1000G | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- VPS13D | c.12677G>T p.R4226M | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS39 | c.2247del p.S750Afs*81 (on ENST00000348544 / NM_001301138.2; = p.S739Afs*81 on NM_015289.5) | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- VWF | c.2685+1G>A p.X895_splice | Splice Site (SNP) | VAF 68/213 reads (32%) | called by muse, mutect2, varscan2
- WASF1 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR77 | c.116-5del | Splice Region (DEL) | VAF 61/211 reads (29%) | called by mutect2, pindel, varscan2
- WDR81 | c.4994G>A p.S1665N (on ENST00000409644 / NM_001163809.2; = p.S614N on NM_152348.4) | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WWC3 | c.2753A>G p.Y918C | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- XPC | c.2194C>A p.L732M | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YEATS2 | c.3629A>T p.E1210V | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, varscan2
- YEATS4 | c.21A>T p.E7D | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- YIF1B | c.673T>G p.F225V (on ENST00000339413 / NM_001039673.3; = p.F210V on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZCCHC14 | c.1256A>G p.Y419C (on ENST00000268616; = p.Y556C on NM_015144.3) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- ZCCHC2 | c.3212T>G p.L1071R | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZFHX3 | c.4910dup p.N1637Kfs*25 | Frame Shift Ins (INS) | VAF 86/259 reads (33%) | called by mutect2, pindel, varscan2
- ZFP28 | c.64del p.R22Afs*12 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- ZMYM4 | c.3523C>T p.R1175* | Nonsense Mutation (SNP) | VAF 94/265 reads (35%) | called by muse, mutect2, varscan2
- ZNF264 | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF285 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2
- ZNF335 | c.3833C>A p.P1278H | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF397 | c.96G>T p.W32C | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZNF469 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF549 | c.1216G>A p.D406N (on ENST00000376233 / NM_001199295.2; = p.D393N on NM_153263.2) | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF564 | c.1479A>T p.R493S | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ZNF578 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF592 | c.1703A>G p.Y568C | Missense Mutation (SNP) | VAF 141/421 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF727 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ZNF770 | c.1286T>C p.L429S | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ABCA7 | c.249G>A p.P83= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- ABCG1 | c.1551C>T p.Y517= | Silent (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- ACAD10 | c.1956G>A p.L652= | Silent (SNP) | VAF 13/238 reads (5%) | called by muse, mutect2
- ADSS2 | c.1131T>C p.A377= | Silent (SNP) | VAF 12/370 reads (3%) | called by muse, mutect2
- AHNAK | c.16503A>G p.G5501= | Silent (SNP) | VAF 92/282 reads (33%) | catalogued as rs777197036; called by muse, mutect2, varscan2
- AJUBA | c.1587T>C p.N529= | Silent (SNP) | VAF 36/306 reads (12%) | called by muse, mutect2, varscan2
- AMH | c.1404C>T p.S468= | Silent (SNP) | VAF 119/310 reads (38%) | called by muse, mutect2, varscan2
- ANAPC1 | c.486T>C p.H162= | Silent (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- ANKRD18A | c.948T>C p.S316= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- ARHGAP42 | c.327C>T p.N109= | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as rs770256541; called by muse, mutect2, varscan2
- ARHGAP45 | c.2340G>A p.K780= | Silent (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.489G>A p.P163= | Silent (SNP) | VAF 69/210 reads (33%) | catalogued as rs753718908, COSV63107344; called by muse, mutect2, varscan2
- ARHGEF15 | c.2127C>A p.L709= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as COSV62724820; called by muse, mutect2
- ASXL2 | c.1740C>T p.S580= | Silent (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- ATG101 | c.147C>T p.T49= | Silent (SNP) | VAF 24/379 reads (6%) | catalogued as rs151182897; called by muse, mutect2
- ATR | c.1998A>G p.V666= | Silent (SNP) | VAF 85/297 reads (29%) | catalogued as rs572889042; called by muse, mutect2, varscan2
- B3GAT2 | c.615C>T p.S205= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs759031870, COSV57774191; called by muse, mutect2, varscan2
- BICDL2 | c.1170G>A p.L390= | Silent (SNP) | VAF 43/151 reads (28%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3606C>T p.T1202= | Silent (SNP) | VAF 69/204 reads (34%) | called by muse, mutect2, varscan2
- BPNT1 | c.54T>C p.I18= | Silent (SNP) | VAF 74/350 reads (21%) | called by muse, mutect2, varscan2
- BRWD3 | c.5178A>G p.A1726= | Silent (SNP) | VAF 37/472 reads (8%) | called by muse, mutect2
- BSN | c.3630A>G p.G1210= | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as rs1477957162; called by muse, mutect2
- C10orf71 | c.3408C>A p.T1136= | Silent (SNP) | VAF 59/180 reads (33%) | called by muse, mutect2, varscan2
- C4orf19 | c.867C>T p.D289= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs372748082, COSV52648828; called by muse, mutect2, varscan2
- CARNS1 | c.240G>C p.S80= | Silent (SNP) | VAF 78/223 reads (35%) | catalogued as COSV57131813; called by muse, mutect2, varscan2
- CATSPER1 | c.1794C>T p.S598= | Silent (SNP) | VAF 226/688 reads (33%) | catalogued as rs777251421, COSV56409198; called by muse, mutect2, varscan2
- CAVIN1 | c.1147C>T p.L383= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- CCDC168 | c.9G>A p.K3= | Silent (SNP) | VAF 28/128 reads (22%) | called by muse, varscan2
- CDK20 | c.423C>G p.L141= | Silent (SNP) | VAF 61/216 reads (28%) | catalogued as rs1354079068; called by muse, mutect2, varscan2
- CDKN1B | c.102C>T p.G34= | Silent (SNP) | VAF 20/412 reads (5%) | called by muse, mutect2
- CHAD | c.537G>A p.S179= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as rs867397902; called by muse, mutect2, varscan2
- CHST2 | c.912G>A p.K304= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV58886767; called by muse, mutect2, varscan2
- CLASRP | c.834G>A p.R278= | Silent (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- CLEC17A | c.828T>C p.D276= | Silent (SNP) | VAF 73/213 reads (34%) | called by muse, mutect2, varscan2
- CLGN | c.1605C>T p.D535= | Silent (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- CLPB | c.462G>A p.L154= | Silent (SNP) | VAF 48/160 reads (30%) | called by muse, varscan2
- CNNM1 | c.594C>T p.G198= | Silent (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- CORO1B | c.1023T>C p.H341= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- CSMD1 | c.2542C>T p.L848= (on ENST00000520002; = p.L847= on NM_033225.6) | Silent (SNP) | VAF 68/262 reads (26%) | catalogued as rs866588898, COSV100141286; called by muse, mutect2
- CXXC5 | c.675G>A p.P225= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs750431013; called by muse, mutect2
- DDX11 | c.2622C>T p.G874= (on ENST00000545668 / NM_152438.2; = p.A826V on NM_004399.3) | Silent (SNP) | VAF 125/308 reads (41%) | called by muse, mutect2, varscan2
- DDX28 | c.618C>T p.G206= | Silent (SNP) | VAF 72/185 reads (39%) | called by muse, mutect2, varscan2
- DDX39B | c.774G>A p.T258= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as rs539629605, COSV63331831; called by muse, mutect2, varscan2
- DGKH | c.2064C>T p.A688= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV54934085; called by muse, mutect2
- DIDO1 | c.2733C>T p.A911= | Silent (SNP) | VAF 94/283 reads (33%) | called by muse, mutect2, varscan2
- DNAH9 | c.13059G>A p.Q4353= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- DNAI1 | c.2049G>A p.A683= | Silent (SNP) | VAF 81/499 reads (16%) | catalogued as rs555612830, COSV54278352; called by muse, mutect2, varscan2
- DNASE1L2 | c.66T>C p.L22= | Silent (SNP) | VAF 29/263 reads (11%) | called by muse, mutect2, varscan2
- DOCK7 | c.3243G>A p.L1081= (on ENST00000635253 / NM_001367561.1; = p.L1050= on NM_033407.3) | Silent (SNP) | VAF 50/203 reads (25%) | called by muse, mutect2, varscan2
- DOK1 | c.1410T>C p.T470= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- DSEL | c.2958C>T p.G986= | Silent (SNP) | VAF 121/385 reads (31%) | catalogued as rs200130664, COSV59489603; called by muse, mutect2, varscan2
- E2F8 | c.177G>A p.P59= | Silent (SNP) | VAF 107/331 reads (32%) | catalogued as rs151240124; called by muse, mutect2, varscan2
- EID2 | c.12G>A p.L4= | Silent (SNP) | VAF 93/251 reads (37%) | called by muse, mutect2, varscan2
- EML4 | c.1575T>C p.T525= | Silent (SNP) | VAF 94/335 reads (28%) | catalogued as rs1213186022; called by muse, mutect2, varscan2
- ENPEP | c.48G>A p.T16= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1225718514, COSV54454125; called by muse, mutect2, varscan2
- ENTHD1 | c.507A>G p.T169= | Silent (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- FAT4 | c.11745C>T p.A3915= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs920683746, COSV58710180; called by muse, mutect2, varscan2
- FLG | c.10284A>G p.Q3428= | Silent (SNP) | VAF 179/742 reads (24%) | called by muse, mutect2, varscan2
- FMO4 | c.1575C>A p.A525= | Silent (SNP) | VAF 107/466 reads (23%) | called by muse, mutect2, varscan2
- FMR1NB | c.150T>C p.A50= | Silent (SNP) | VAF 31/342 reads (9%) | called by muse, mutect2
- FOXO6 | c.54G>A p.P18= | Silent (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
- FUBP3 | c.564G>A p.L188= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV60514352; called by muse, varscan2
- GAB3 | c.1182G>A p.V394= | Silent (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- GAPVD1 | c.2205G>T p.L735= | Silent (SNP) | VAF 101/266 reads (38%) | called by muse, mutect2, varscan2
- GAREM2 | c.1539G>A p.L513= | Silent (SNP) | VAF 80/231 reads (35%) | catalogued as rs1434205292; called by muse, mutect2, varscan2
- GCKR | c.963C>T p.S321= | Silent (SNP) | VAF 180/552 reads (33%) | catalogued as rs1212517032; called by muse, mutect2, varscan2
- GDF2 | c.207C>T p.S69= | Silent (SNP) | VAF 76/227 reads (33%) | catalogued as rs1229631161; called by muse, mutect2, varscan2
- GDF7 | c.1008C>T p.G336= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs763741972, COSV55348670; called by muse, mutect2, varscan2
- GLI2 | c.2316G>A p.S772= (on ENST00000361492 / NM_001374353.1; = p.S789= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs758156846; called by muse, mutect2, varscan2
- GORAB | c.894A>G p.V298= | Silent (SNP) | VAF 135/633 reads (21%) | called by muse, mutect2, varscan2
- GPC6 | c.1512C>T p.D504= | Silent (SNP) | VAF 193/595 reads (32%) | catalogued as rs776151903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIK3 | c.672C>T p.G224= | Silent (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- GRIN3A | c.189C>T p.R63= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs898371663; called by muse, mutect2, varscan2
- GRM3 | c.804C>T p.N268= | Silent (SNP) | VAF 65/214 reads (30%) | catalogued as COSV64481098; called by muse, mutect2, varscan2
- GRM6 | c.2157G>T p.R719= | Silent (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- HSD3B2 | c.384C>T p.A128= | Silent (SNP) | VAF 146/370 reads (39%) | catalogued as rs775037341; called by muse, mutect2, varscan2
- IGFALS | c.1815C>T p.C605= | Silent (SNP) | VAF 54/176 reads (31%) | catalogued as COSV51905382; called by muse, mutect2, varscan2
- INPP5F | c.801C>A p.T267= | Silent (SNP) | VAF 61/177 reads (34%) | called by muse, mutect2, varscan2
- IRF2BPL | c.1584G>A p.P528= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- IRX4 | c.1470G>A p.P490= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs755882161; called by muse, mutect2, varscan2
- ISX | c.31A>C p.R11= | Silent (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- ITGB6 | c.378C>T p.R126= | Silent (SNP) | VAF 86/292 reads (29%) | catalogued as COSV99324235; called by muse, mutect2, varscan2
- KIF1A | c.3948T>C p.F1316= (on ENST00000320389 / NM_001379639.1; = p.F1308= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 95/291 reads (33%) | called by muse, mutect2, varscan2
- KRTAP9-1 | c.126C>T p.C42= | Silent (SNP) | VAF 148/443 reads (33%) | called by muse, mutect2, varscan2
- LAMP1 | c.636C>T p.P212= | Silent (SNP) | VAF 53/181 reads (29%) | catalogued as rs376761620; called by muse, mutect2, varscan2
- LARP4 | c.1971T>C p.P657= | Silent (SNP) | VAF 120/337 reads (36%) | called by muse, mutect2, varscan2
- LMO7 | c.3099G>A p.T1033= (on ENST00000357063; = p.T714= on NM_005358.5) | Silent (SNP) | VAF 85/302 reads (28%) | catalogued as rs1277081730, COSV58549898; called by muse, mutect2, varscan2
- LRP1 | c.2706C>T p.C902= | Silent (SNP) | VAF 10/257 reads (4%) | catalogued as rs1209557859; called by muse, mutect2
- LRRK2 | c.3072G>A p.T1024= | Silent (SNP) | VAF 85/211 reads (40%) | catalogued as rs201407012, COSV54155014; called by muse, mutect2, varscan2
- MACF1 | c.6042G>A p.G2014= | Silent (SNP) | VAF 83/232 reads (36%) | called by muse, mutect2, varscan2
- MARCHF1 | c.294C>T p.R98= (on ENST00000274056; = p.R81= on NM_017923.4) | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs1169387384; called by muse, mutect2, varscan2
- MDGA1 | c.291T>C p.R97= | Silent (SNP) | VAF 7/175 reads (4%) | called by muse, mutect2
- MEGF11 | c.1854C>T p.C618= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as rs376519163, COSV99988600; called by muse, mutect2
- MEI1 | c.1089G>A p.T363= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as rs1408217272, COSV55903844; called by muse, mutect2, varscan2
- MMAA | c.625A>C p.R209= | Silent (SNP) | VAF 121/354 reads (34%) | called by muse, mutect2, varscan2
- MN1 | c.1026G>A p.Q342= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- MPST | c.165G>A p.P55= (on ENST00000341116 / NM_001369904.2; = p.P75= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs932673398; called by muse, mutect2, varscan2
- MROH1 | c.2028C>T p.A676= | Silent (SNP) | VAF 75/278 reads (27%) | called by muse, mutect2, varscan2
- MTARC1 | c.738C>T p.C246= | Silent (SNP) | VAF 94/417 reads (23%) | catalogued as rs754433799, COSV100856263; called by muse, mutect2, varscan2
- MTCL1 | c.2391C>T p.S797= (on ENST00000306329 / NM_001378206.1; = p.S437= on NM_015210.4) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs201042941; called by muse, varscan2
- MTHFD1L | c.2181G>A p.K727= | Silent (SNP) | VAF 32/247 reads (13%) | called by muse, mutect2, varscan2
- MXRA5 | c.6093C>T p.A2031= | Silent (SNP) | VAF 70/188 reads (37%) | catalogued as rs780385533; called by muse, mutect2, varscan2
- MYCBPAP | c.1887C>T p.H629= | Silent (SNP) | VAF 115/329 reads (35%) | catalogued as rs766330950, COSV100088569; called by muse, mutect2, varscan2
- MYG1 | c.807A>G p.A269= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as rs754202460; called by muse, mutect2
- MYO1F | c.1002C>T p.S334= | Silent (SNP) | VAF 78/246 reads (32%) | catalogued as rs766772743; called by muse, mutect2, varscan2
- MYOG | c.237C>T p.S79= | Silent (SNP) | VAF 117/464 reads (25%) | catalogued as rs775135850, COSV99613824; called by muse, mutect2, varscan2
- NCL | c.750C>T p.D250= | Silent (SNP) | VAF 113/367 reads (31%) | catalogued as rs1457252148, COSV59545316; called by muse, mutect2, varscan2
- NCR3LG1 | c.972G>A p.R324= | Silent (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- NMT2 | c.774G>A p.S258= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs141559838; called by muse, mutect2, varscan2
- NRXN1 | c.588C>T p.P196= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs201644834, COSV68009548, COSV68019434, COSV68040799; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT18 | c.99G>T p.P33= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- NUP210L | c.3390G>A p.G1130= | Silent (SNP) | VAF 89/457 reads (19%) | catalogued as rs781464956; called by muse, mutect2, varscan2
- OR13J1 | c.57C>T p.G19= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs375093972; called by muse, mutect2, varscan2
- OR2L8 | c.636T>C p.G212= | Silent (SNP) | VAF 92/376 reads (24%) | catalogued as rs770497170; called by muse, mutect2, varscan2
- OR2T12 | c.240G>A p.A80= | Silent (SNP) | VAF 41/299 reads (14%) | catalogued as rs772509947, COSV58779446; called by muse, mutect2, varscan2
- OXCT1 | c.258T>C p.T86= | Silent (SNP) | VAF 98/451 reads (22%) | catalogued as rs759374202; called by muse, mutect2, varscan2
- PAK6 | c.1635C>T p.F545= | Silent (SNP) | VAF 94/235 reads (40%) | catalogued as rs763046488; called by muse, mutect2, varscan2
- PCDHB11 | c.1773G>A p.A591= | Silent (SNP) | VAF 152/727 reads (21%) | called by muse, varscan2
- PCDHB5 | c.945C>T p.N315= | Silent (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- PCNT | c.8115C>T p.C2705= | Silent (SNP) | VAF 96/286 reads (34%) | catalogued as rs756904669, COSV64026795; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDZD8 | c.2247G>A p.T749= | Silent (SNP) | VAF 33/288 reads (11%) | catalogued as rs138837693; called by muse, mutect2, varscan2
167 further variants in this file (0 protein-altering or splice-affecting, 60 silent, 107 other) are not listed here.
